Somatic mutation profile of cancer-model specimen HCM-STAN-0777-C25-85S (3D Organoid, passage 7; aliquot HCM-STAN-0777-C25-85S-01D-A88H-36), derived from the recurrence tumor of HCMI case HCM-STAN-0777-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 68.0 years (24,820 days).
Specimen HCM-STAN-0777-C25-85S: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4a1415-a503-4049-8f99-3c3b9c5a44c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0777-C25-10A (Blood Derived Normal), aliquot HCM-STAN-0777-C25-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/677d19f5-4098-4828-89fe-c69997ace107

The open-access MAF lists 96 somatic variants for this specimen: 70 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 22, Frame Shift Ins 3, Nonsense Mutation 3, In Frame Del 2, 3'UTR 2, Intron 2, Splice Site 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL2A1 | c.3589G>A p.G1197S | Missense Mutation (SNP) | VAF 104/511 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs121912870, CM910093; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 253/528 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 391/391 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS10 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 262/497 reads (53%) | catalogued as COSV99546265; called by muse, mutect2, varscan2
- ADGRB1 | c.4004G>A p.R1335Q | Missense Mutation (SNP) | VAF 242/747 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs753823931; called by muse, mutect2, varscan2
- AFG3L2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 116/247 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52313760, COSV99301591; called by muse, mutect2, varscan2
- BAHCC1 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 212/914 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs944741353; called by muse, mutect2, varscan2
- BSN | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 232/452 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as rs962864521; called by muse, mutect2, varscan2
- CBFA2T2 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 48/1023 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV60076071; called by muse, mutect2
- CDX1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 154/482 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV51568430; called by muse, mutect2, varscan2
- CHRM3 | c.1496C>A p.A499D | Missense Mutation (SNP) | VAF 216/719 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55107703; called by mutect2, varscan2
- CKM | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 76/417 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1313579937, COSV99488903; called by muse, mutect2, varscan2
- COL8A1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 165/506 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs558799692; called by muse, mutect2, varscan2
- CSMD1 | c.7744G>A p.G2582S (on ENST00000520002; = p.G2581S on NM_033225.6) | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs200463703, COSV100153026; called by muse, mutect2, varscan2
- DAGLB | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 26/668 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs1426455501; called by muse, mutect2
- HECW1 | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 163/640 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760980182, COSV67841998; called by muse, varscan2
- KCNU1 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 124/207 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV67757825; called by muse, mutect2, varscan2
- KRTAP20-1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 213/469 reads (45%) | PolyPhen probably damaging (0.997); catalogued as COSV58168977; called by muse, mutect2
- LARS1 | c.2181G>C p.L727F (on ENST00000394434 / NM_020117.11; = p.L700F on NM_016460.3) | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50972193; called by muse, mutect2, varscan2
- LOXL2 | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 288/868 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs760460697; called by muse, mutect2, varscan2
- MCOLN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 30/547 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs201171839, COSV52295381; called by muse, mutect2
- PTAR1 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 16/420 reads (4%) | catalogued as rs866087896; called by muse, mutect2
- PTPRN | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 173/522 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775161902, COSV55351410; called by muse, mutect2, varscan2
- RSPH6A | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 179/368 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1448069188; called by muse, mutect2, varscan2
- SLC16A14 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 138/432 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202122599, COSV54619632; called by muse, varscan2
- SLC38A4 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 188/378 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs760817445, COSV56966129; called by muse, varscan2
- SOGA3 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 227/418 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100847014; called by muse, mutect2, varscan2
- TMEM74 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52463842; called by muse, mutect2, varscan2
- AC098582.1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 121/238 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ADAM19 | c.2183A>G p.N728S | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2
- ADGRG4 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 11/398 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- AURKAIP1 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 164/632 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- AZU1 | c.587T>A p.I196N | Missense Mutation (SNP) | VAF 160/382 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CADM3 | c.523G>A p.E175K (on ENST00000368125 / NM_001127173.3; = p.E209K on NM_021189.5) | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.006); called by muse, mutect2
- CDKN2AIPNL | c.167_183del p.D56Gfs*22 | Frame Shift Del (DEL) | VAF 390/709 reads (55%) | called by mutect2, pindel, varscan2
- CEP83 | c.1397dup p.N466Kfs*2 | Frame Shift Ins (INS) | VAF 73/330 reads (22%) | called by mutect2, varscan2
- CX3CL1 | c.1060T>C p.C354R | Missense Mutation (SNP) | VAF 233/677 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CYP4X1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2
- DDX31 | c.2510C>T p.T837I | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- DLL1 | c.1918G>C p.D640H | Missense Mutation (SNP) | VAF 296/627 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- DLX4 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 492/985 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ELF3 | c.386-1G>T p.X129_splice | Splice Site (SNP) | VAF 154/335 reads (46%) | called by muse, mutect2, varscan2
- ELF3 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 158/343 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPS15 | c.1992_2015del p.A667_F674del | In Frame Del (DEL) | VAF 65/315 reads (21%) | called by mutect2, pindel, varscan2
- FAM53C | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 201/623 reads (32%) | called by muse, mutect2, varscan2
- GAREM2 | c.1429G>C p.V477L | Missense Mutation (SNP) | VAF 324/505 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPNMB | c.170A>C p.K57T | Missense Mutation (SNP) | VAF 140/557 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- GYS2 | c.2112A>T p.*704Cext*11 | Nonstop Mutation (SNP) | VAF 97/398 reads (24%) | called by muse, mutect2, varscan2
- KDM6A | c.185_189dup p.E64Ffs*22 | Frame Shift Ins (INS) | VAF 136/143 reads (95%) | called by mutect2, varscan2
- KTN1 | c.2711A>G p.N904S | Missense Mutation (SNP) | VAF 144/293 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LRATD1 | c.395A>C p.Q132P | Missense Mutation (SNP) | VAF 60/1053 reads (6%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- LRP1 | c.4393G>A p.G1465S | Missense Mutation (SNP) | VAF 283/633 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSH6 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 146/492 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- NBEAL2 | c.2924A>G p.Q975R | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2
- NKX1-2 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 216/738 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- NOP14 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- NUP62 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 168/329 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR5J2 | c.881A>G p.N294S | Missense Mutation (SNP) | VAF 137/392 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, varscan2
- OR5K2 | c.652T>G p.Y218D | Missense Mutation (SNP) | VAF 98/341 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.2243T>G p.V748G | Missense Mutation (SNP) | VAF 140/563 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB10 | c.2011C>A p.L671M | Missense Mutation (SNP) | VAF 638/841 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCD11 | c.2423C>G p.A808G | Missense Mutation (SNP) | VAF 124/425 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- POU2F1 | c.253A>G p.S85G (on ENST00000541643 / NM_001365848.1; = p.S108G on NM_002697.4) | Missense Mutation (SNP) | VAF 132/533 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS17 | c.94T>C p.W32R | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SEC61A2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 119/339 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- TFDP2 | c.314G>C p.R105T (on ENST00000489671 / NM_001178139.2; = p.R44T on NM_006286.5) | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TRAF3IP3 | c.801_802insC p.V268Rfs*13 | Frame Shift Ins (INS) | VAF 92/430 reads (21%) | called by mutect2, pindel, varscan2
- TRIL | c.1115_1119delinsCC p.R372_W373delinsP | In Frame Del (DEL) | VAF 143/896 reads (16%) | called by pindel, varscan2*
- ULBP2 | c.551A>C p.Y184S | Missense Mutation (SNP) | VAF 253/509 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF234 | c.497A>T p.H166L | Missense Mutation (SNP) | VAF 143/338 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ADAMTS2 | c.3351C>T p.D1117= | Silent (SNP) | VAF 360/554 reads (65%) | catalogued as rs777279065, COSV104380885; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ARL14EPL | c.54T>C p.H18= | Silent (SNP) | VAF 130/423 reads (31%) | catalogued as COSV59948482; called by muse, mutect2, varscan2
- CSF1 | c.597C>T p.S199= | Silent (SNP) | VAF 32/626 reads (5%) | catalogued as rs765879124, COSV100294306; called by muse, mutect2
- CSMD1 | c.1089C>T p.S363= | Silent (SNP) | VAF 89/256 reads (35%) | catalogued as rs576618220, COSV68174188; called by muse, mutect2, varscan2
- CUX2 | c.2355C>T p.F785= | Silent (SNP) | VAF 622/1232 reads (50%) | catalogued as COSV55637281; called by muse, varscan2
- DCDC1 | c.4326G>A p.T1442= (on ENST00000597505 / NM_001367979.1; = p.T549= on NM_020869.3) | Silent (SNP) | VAF 81/283 reads (29%) | catalogued as rs761489354, COSV58004359; called by muse, mutect2, varscan2
- DNAH6 | c.8322C>T p.D2774= | Silent (SNP) | VAF 153/505 reads (30%) | catalogued as rs922139524, COSV52861544; called by muse, mutect2, varscan2
- FZD10 | c.1362G>T p.P454= | Silent (SNP) | VAF 178/775 reads (23%) | called by muse, varscan2
- GTPBP1 | c.1782G>A p.T594= | Silent (SNP) | VAF 162/879 reads (18%) | catalogued as rs143672429; called by muse, mutect2, varscan2
- KSR2 | c.1593G>A p.S531= | Silent (SNP) | VAF 221/1047 reads (21%) | catalogued as rs762371454, COSV56675038; called by muse, mutect2, varscan2
- LRRC38 | c.504C>T p.S168= | Silent (SNP) | VAF 36/775 reads (5%) | catalogued as rs1459540469; called by muse, mutect2
- MMP24 | c.1395G>A p.G465= | Silent (SNP) | VAF 190/869 reads (22%) | catalogued as rs1464489370; called by muse, mutect2, varscan2
- PCDHA2 | c.2091C>T p.N697= | Silent (SNP) | VAF 209/675 reads (31%) | catalogued as COSV65367452; called by muse, mutect2, varscan2
- PGAM5 | c.318C>G p.S106= | Silent (SNP) | VAF 352/686 reads (51%) | called by muse, mutect2, varscan2
- PJA2 | c.172C>A p.R58= | Silent (SNP) | VAF 119/397 reads (30%) | called by muse, mutect2, varscan2
- PLEKHG2 | c.273G>C p.P91= | Silent (SNP) | VAF 306/558 reads (55%) | catalogued as COSV52680558; called by muse, mutect2, varscan2
- PRKCG | c.759C>T p.N253= | Silent (SNP) | VAF 261/629 reads (41%) | catalogued as rs751772455, COSV54726550; called by muse, mutect2, varscan2
- RFX6 | c.1218T>C p.V406= | Silent (SNP) | VAF 19/282 reads (7%) | called by muse, mutect2
- RTL1 | c.2682C>T p.D894= | Silent (SNP) | VAF 156/753 reads (21%) | catalogued as COSV104432787; called by muse, mutect2, varscan2
- UBOX5 | c.99T>C p.D33= | Silent (SNP) | VAF 214/447 reads (48%) | catalogued as rs1568471529; called by muse, mutect2, varscan2
- WHRN | c.2655C>T p.A885= | Silent (SNP) | VAF 201/420 reads (48%) | catalogued as rs775402871, COSV54335188; called by muse, mutect2, varscan2
- ZNF837 | c.1395C>T p.H465= | Silent (SNP) | VAF 254/636 reads (40%) | called by muse, mutect2, varscan2
- GPR68 | c.*305G>C | 3'UTR (SNP) | VAF 28/750 reads (4%) | called by muse, mutect2
- ILRUN | c.*2318A>G | 3'UTR (SNP) | VAF 88/218 reads (40%) | called by muse, mutect2, varscan2
- PGA5 | c.657-83G>A | Intron (SNP) | VAF 291/819 reads (36%) | catalogued as rs1006106706; called by muse, mutect2, varscan2
- WNK1 | c.2140-2230C>A | Intron (SNP) | VAF 166/839 reads (20%) | catalogued as COSV60037015; called by muse, mutect2, varscan2
